Somatic mutation profile of tumor specimen 0DVCF8 from CCDI case PBCMSE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.2 years (4,091 days).
Specimen 0DVCF8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9090f126-d3ea-4b3c-b1a2-a17a1ca0f1a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVCFY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/489ee49a-167a-49ce-81d4-9a32ddcf9ef8

The open-access MAF lists 11 somatic variants for this specimen: 4 protein-altering or splice-affecting, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, 3'UTR 2, Missense Mutation 2, Frame Shift Del 1, 5'UTR 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TRMT10A | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 353/804 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1225912691; called by muse, mutect2, varscan2
- VGLL1 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 38/705 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778398693; called by muse, mutect2
- SLC6A13 | c.936-3C>T | Splice Region (SNP) | VAF 95/189 reads (50%) | called by muse, mutect2, varscan2
- TESK2 | c.1580_1599del p.R527Mfs*7 | Frame Shift Del (DEL) | VAF 107/226 reads (47%) | called by mutect2, varscan2
- AC125421.1 | n.880G>A | RNA (SNP) | VAF 155/355 reads (44%) | catalogued as rs558982590; called by muse, mutect2, varscan2
- BIRC6 | c.6593-24A>G | Intron (SNP) | VAF 87/173 reads (50%) | called by muse, mutect2, varscan2
- EIF4A1 | c.906+13G>A | Intron (SNP) | VAF 24/454 reads (5%) | catalogued as rs372471773; called by muse, mutect2
- LMOD1 | c.*85C>G | 3'UTR (SNP) | VAF 65/154 reads (42%) | called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 19/172 reads (11%) | called by muse, varscan2
- TBXA2R | c.*710C>T | 3'UTR (SNP) | VAF 79/185 reads (43%) | called by muse, mutect2, varscan2
